CCDI case PBCEFH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6e93cac9-3fbb-420c-9726-1cd70eac8aa8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.4 years (4,897 days).

Biospecimens (2 samples)
- Sample 0DQ7V2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7VA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
